TCGA case TCGA-PC-A5DN — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc18ccea-b332-4fac-b49b-1e0217ad025b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Dead; Days to death: 1,175 days (3.2 years).

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 77.8 years (28,421 days); Year of diagnosis: 2005; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 20.
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Days to follow up: 1,175 days (3.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PC-A5DN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 510 mg.
  Slide TCGA-PC-A5DN-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-PC-A5DN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-PC-A5DN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,175 days; disease-specific survival: no event (censored), 1,175 days; progression-free interval: no event (censored), 1,175 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-PC-A5DN-01A-12D-A27O-01): tumor purity 0.61, ploidy 2.06, whole-genome doublings 0.
